Somatic mutation profile of tumor specimen C3L-05175-03 (aliquot CPT0277520006) from CPTAC case C3L-05175, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 62.9 years (22,975 days).
Specimen C3L-05175-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3cf71c0-5b17-4455-bc54-b1f96170b03f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05175-31 (Blood Derived Normal), aliquot CPT0277580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90bce46e-f670-4000-b5c2-25de91d7e430

The open-access MAF lists 451 somatic variants for this specimen: 295 protein-altering or splice-affecting, 143 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 261, Silent 143, Nonsense Mutation 23, Intron 10, Splice Region 4, Frame Shift Del 3, 3'UTR 2, Nonstop Mutation 1, 5'UTR 1, In Frame Ins 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 155/479 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs11547328, CM960267, COSV56984534, COSV56985244; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.6013C>T p.R2005* | Nonsense Mutation (SNP) | VAF 42/255 reads (16%) | catalogued as rs587784173, CM032979, CM1513402, COSV61772702; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 140/303 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757152139; called by muse, mutect2, varscan2
- ACOT7 | c.316C>T p.R106C (on ENST00000377855 / NM_181864.3; = p.R96C on NM_007274.4) | Missense Mutation (SNP) | VAF 134/297 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745574437, COSV64113327; called by muse, mutect2, varscan2
- ADAM28 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 165/540 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs1366233563; called by muse, mutect2, varscan2
- ADAMTSL3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 127/378 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774715008, COSV54469980; called by muse, mutect2, varscan2
- ADGRL4 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 189/495 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1243424468; called by muse, mutect2, varscan2
- AKR1C1 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 106/284 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV66498819; called by muse, mutect2, varscan2
- ANKRD31 | c.4450G>A p.E1484K | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57156758; called by muse, mutect2, varscan2
- AP1M2 | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 191/570 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs979201258; called by muse, mutect2, varscan2
- ARID2 | c.2416C>T p.Q806* | Nonsense Mutation (SNP) | VAF 108/364 reads (30%) | catalogued as rs1565622483; called by muse, mutect2, varscan2
- ARID2 | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 124/385 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV57607135; called by muse, mutect2, varscan2
- BCHE | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 169/525 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52262845; called by muse, mutect2, varscan2
- BPIFB4 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 253/638 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs753941963, COSV64951254; called by muse, mutect2, varscan2
- BRWD3 | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 77/335 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs775682673; called by muse, mutect2, varscan2
- CASS4 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 221/587 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs747288992, COSV64386490, COSV64387137; called by muse, mutect2, varscan2
- CCBE1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 194/509 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); catalogued as rs868101186, COSV67949619; called by muse, mutect2, varscan2
- CCDC130 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 209/620 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as rs1242438855; called by muse, mutect2, varscan2
- CDH17 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 120/350 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs547907658; called by muse, mutect2, varscan2
- CENPP | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 399/601 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0.096); catalogued as rs1242459672, COSV99845532; called by muse, mutect2, varscan2
- CFHR2 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 152/501 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV66381542; called by muse, mutect2, varscan2
- CFTR | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 149/471 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs906983070, COSV50048120; called by muse, mutect2, varscan2
- CILP | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 208/589 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200303555; called by muse, mutect2, varscan2
- CLDN8 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 164/511 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as rs373504217; called by muse, mutect2, varscan2
- COL6A5 | c.4453G>A p.G1485R | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55217515; called by muse, mutect2, varscan2
- COTL1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 97/350 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs747265049, COSV52289942; called by muse, mutect2, varscan2
- CRB2 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 262/402 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs745391116, COSV100749785; called by mutect2, varscan2
- CRY2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 253/455 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV69889420; called by muse, mutect2, varscan2
- CSMD1 | c.5612G>A p.G1871E (on ENST00000520002; = p.G1870E on NM_033225.6) | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761601416, COSV59299434; called by muse, mutect2, varscan2
- CSMD3 | c.7987C>T p.R2663* (on ENST00000297405 / NM_001363185.1; = p.R2559* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 197/525 reads (38%) | catalogued as rs1432657584, COSV52100177, COSV52156018; called by muse, mutect2, varscan2
- CTAGE9 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 214/340 reads (63%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV100020317; called by muse, mutect2, varscan2
- DCAF4L1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 131/410 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs553184430; called by muse, mutect2, varscan2
- DCLK2 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 60/367 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV56205980; called by muse, mutect2, varscan2
- DMC1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV53258888; called by muse, mutect2, varscan2
- DNAH7 | c.6950G>A p.R2317Q | Missense Mutation (SNP) | VAF 160/519 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs1262544571, COSV56750341, COSV56756852; called by muse, mutect2, varscan2
- DPPA4 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 200/555 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs267599536, COSV100169760; called by muse, mutect2, varscan2
- ENAM | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 203/567 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs745482726, COSV68536094; called by muse, mutect2, varscan2
- ENTPD5 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 145/313 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.134); catalogued as COSV53178074; called by muse, mutect2, varscan2
- EPHA2 | c.2357C>G p.P786R | Missense Mutation (SNP) | VAF 146/443 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760459530, COSV100626182, COSV64452565; called by muse, mutect2, varscan2
- EPHX3 | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 99/302 reads (33%) | catalogued as rs187289470; called by muse, mutect2, varscan2
- EVL | c.992C>T p.S331L (on ENST00000402714 / NM_001330221.2; = p.S333L on NM_016337.3) | Missense Mutation (SNP) | VAF 155/295 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV67375968; called by muse, mutect2, varscan2
- FAM47C | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 213/432 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.208); catalogued as COSV63723912; called by muse, mutect2, varscan2
- FBN3 | c.6478C>T p.L2160F | Missense Mutation (SNP) | VAF 130/452 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV54468513; called by muse, mutect2
- FMN2 | c.2947G>A p.G983R | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as rs750401905, COSV60430412; called by muse, mutect2, varscan2
- FMN2 | c.2948G>A p.G983E | Missense Mutation (SNP) | VAF 71/366 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.324); catalogued as COSV60422121; called by muse, varscan2
- GLP1R | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 276/452 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs765821452; called by muse, mutect2, varscan2
- GOLGB1 | c.5615C>T p.T1872I | Missense Mutation (SNP) | VAF 136/409 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs765643338; called by muse, mutect2, varscan2
- GP6 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 323/944 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV59979172; called by muse, mutect2
- HDX | c.818A>T p.Y273F | Missense Mutation (SNP) | VAF 208/673 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.265); catalogued as COSV52977389; called by muse, mutect2, varscan2
- HHIPL2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 124/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564422; called by muse, mutect2, varscan2
- HUS1B | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 390/672 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1417856460; called by muse, mutect2, varscan2
- HYDIN | c.2122G>T p.G708W | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55479205; called by muse, mutect2, varscan2
- ICE2 | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 150/467 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866101315; called by muse, mutect2, varscan2
- IFT80 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 144/421 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100425233, COSV58446297; called by muse, mutect2, varscan2
- INTS13 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1443820645; called by muse, mutect2, varscan2
- IRX1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 62/554 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV57361238; called by muse, varscan2
- ITIH3 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1171893686, COSV101407173; called by muse, mutect2, varscan2
- KIAA1522 | c.560G>A p.R187Q (on ENST00000373480 / NM_001198972.2; = p.R246Q on NM_020888.3) | Missense Mutation (SNP) | VAF 225/675 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs765324176; called by muse, mutect2, varscan2
- KLHL32 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 303/470 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143481422, COSV65110747; called by muse, mutect2, varscan2
- KRT14 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 135/379 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV99391058; called by muse, mutect2, varscan2
- KRTAP6-2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 151/427 reads (35%) | PolyPhen possibly damaging (0.823); catalogued as COSV58182455; called by muse, mutect2, varscan2
- KSR2 | c.2405C>T p.T802M | Missense Mutation (SNP) | VAF 203/547 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563602140, COSV56674686; called by muse, mutect2, varscan2
- LIFR | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 140/351 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs143621762; called by muse, mutect2, varscan2
- LLGL2 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 180/550 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51379509; called by muse, mutect2, varscan2
- LPAR4 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 208/665 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1350858114, COSV70912427; called by muse, mutect2, varscan2
- LRPPRC | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756994306, COSV53243771; called by muse, mutect2, varscan2
- LRRC55 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 179/335 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV73006536; called by muse, mutect2, varscan2
- MAGEA12 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 288/841 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.411); catalogued as rs1556833511, COSV63294502; called by muse, mutect2, varscan2
- MGAM | c.4254G>A p.W1418* | Nonsense Mutation (SNP) | VAF 92/305 reads (30%) | catalogued as COSV72074467; called by muse, mutect2, varscan2
- MOCS3 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 197/574 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99724173; called by muse, mutect2, varscan2
- MPRIP | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 197/347 reads (57%) | catalogued as COSV100506178; called by muse, mutect2, varscan2
- MUC16 | c.20751G>A p.M6917I | Missense Mutation (SNP) | VAF 155/534 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs756802696, COSV67453508; called by muse, mutect2, varscan2
- MUC16 | c.14399C>T p.S4800L | Missense Mutation (SNP) | VAF 135/477 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.943); catalogued as rs777222644; called by muse, mutect2, varscan2
- MUC17 | c.9244G>A p.E3082K | Missense Mutation (SNP) | VAF 200/689 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.636); catalogued as COSV60288280; called by muse, mutect2, varscan2
- MXRA5 | c.2611G>A p.G871R | Missense Mutation (SNP) | VAF 223/454 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54227223; called by muse, mutect2, varscan2
- NEO1 | c.4129C>T p.P1377S | Missense Mutation (SNP) | VAF 167/485 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV56076140; called by muse, mutect2, varscan2
- NEXMIF | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 204/615 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747436946, COSV50021850; called by muse, mutect2, varscan2
- NLRP7 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 226/762 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0.054); catalogued as COSV60178691; called by mutect2, varscan2
- NOTCH4 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 282/442 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66679028; called by muse, mutect2, varscan2
- OR2L5 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 88/332 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs566745463; called by muse, mutect2, varscan2
- OR2T33 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 270/900 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1298197518, COSV58813710; called by muse, mutect2, varscan2
- OR4C3 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 169/300 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60583951; called by muse, mutect2, varscan2
- OR56A1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 168/368 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs944573245; called by muse, mutect2, varscan2
- OR56A5 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 173/349 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60827363; called by muse, mutect2, varscan2
- OR5AS1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57981336; called by muse, mutect2, varscan2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 120/377 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, varscan2
- PAX8 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 117/379 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1397854984, COSV54506516; called by muse, mutect2, varscan2
- PCDHB3 | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 341/817 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV50616653; called by muse, mutect2, varscan2
- PGBD2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 226/632 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV100252202, COSV61400484; called by muse, mutect2, varscan2
- PKIA | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 134/370 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs536361273, COSV61914497; called by muse, mutect2, varscan2
- PLCXD3 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.956); catalogued as COSV60609794; called by muse, mutect2, varscan2
- POTEA | c.1012G>A p.D338N (on ENST00000519951 / NM_001005365.2; = p.D292N on NM_001002920.1) | Missense Mutation (SNP) | VAF 83/227 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs781436238; called by muse, mutect2, varscan2
- POTEH | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 100/1236 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs868498912, COSV58882009; called by muse, varscan2
- PPEF2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 123/414 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.138); catalogued as rs1375007062; called by muse, mutect2, varscan2
- PRB3 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 232/719 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.414); catalogued as rs745804122; called by muse, mutect2, varscan2
- PRKCB | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 174/534 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV57774019; called by muse, mutect2, varscan2
- PSG1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 201/557 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs1058692; called by muse, mutect2, varscan2
- PTPRF | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 240/733 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as rs769997975; called by muse, mutect2, varscan2
- PTPRQ | c.2194G>A p.E732K (on ENST00000616559; = p.E690K on NM_001145026.2) | Missense Mutation (SNP) | VAF 153/451 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs866364601, COSV99884554; called by muse, mutect2, varscan2
- QSER1 | c.2926C>T p.P976S (on ENST00000399302; = p.P1105S on NM_001076786.3) | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1008435544; called by muse, mutect2, varscan2
- RADIL | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 252/867 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as rs140891342; called by muse, mutect2, varscan2
- RBL2 | c.3008G>T p.G1003V | Missense Mutation (SNP) | VAF 168/538 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50878889; called by muse, mutect2, varscan2
- RBM11 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 200/811 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1367048129; called by muse, mutect2, varscan2
- RBM27 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 95/452 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV54592468; called by muse, mutect2, varscan2
- RBMXL3 | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 268/800 reads (34%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs1273797983, COSV57754029; called by muse, mutect2, varscan2
- RHBDL1 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 192/549 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as rs752858138; called by muse, mutect2, varscan2
- RNF17 | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 118/356 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55042018; called by muse, mutect2, varscan2
- SARAF | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 168/684 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs764561085; called by muse, mutect2, varscan2
- SCN10A | c.3703G>A p.A1235T | Missense Mutation (SNP) | VAF 362/486 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs950779366; called by muse, mutect2, varscan2
- SDHAF3 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 157/490 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1235647843; called by muse, mutect2, varscan2
- SEMG2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 135/450 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.355); catalogued as COSV65647261; called by muse, mutect2, varscan2
- SIM1 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 211/340 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.659); catalogued as rs763116551, COSV53490685; called by muse, mutect2, varscan2
- SLC12A5 | c.575C>T p.S192F (on ENST00000454036 / NM_001134771.2; = p.S169F on NM_020708.5) | Missense Mutation (SNP) | VAF 116/379 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54792432; called by muse, mutect2, varscan2
- SLC25A42 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 107/345 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV59379479, COSV59380053; called by muse, mutect2, varscan2
- SLC27A2 | c.1442T>C p.V481A | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV51058092; called by muse, mutect2, varscan2
- SLC2A4RG | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 112/369 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55514696; called by muse, mutect2, varscan2
- SV2C | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 127/339 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs761310792, COSV59216339; called by muse, mutect2, varscan2
- TBC1D8 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 186/552 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs1410641105; called by muse, mutect2, varscan2
- TBX20 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs766104278; called by muse, mutect2, varscan2
- TEK | c.1623C>T p.I541= | Splice Region (SNP) | VAF 121/229 reads (53%) | catalogued as rs762557707; called by muse, mutect2, varscan2
- TGFBR3 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 173/649 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV53024545; called by muse, mutect2, varscan2
- THSD7A | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 143/472 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051817932, COSV70264321; called by muse, mutect2, varscan2
- TJP3 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 144/494 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236623504; called by muse, mutect2
- TLL1 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 136/422 reads (32%) | catalogued as rs774503754; called by muse, mutect2, varscan2
- TNRC18 | c.5450C>T p.S1817L | Missense Mutation (SNP) | VAF 139/388 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs371357521; called by muse, mutect2, varscan2
- TRAV20 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 118/363 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.492); catalogued as rs1225872622; called by muse, mutect2, varscan2
- TRPC4AP | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 212/636 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.045); catalogued as rs1250903344; called by muse, mutect2, varscan2
- TRPV4 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 127/406 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.141); catalogued as rs756526036, COSV55686285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.75656G>A p.G25219E (on ENST00000591111; = p.G17795E on NM_003319.4) | Missense Mutation (SNP) | VAF 138/389 reads (35%) | PolyPhen probably damaging (1); catalogued as COSV59905157; called by muse, mutect2, varscan2
- UBASH3A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 164/539 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs776278043; called by muse, mutect2, varscan2
- WDR49 | c.1627G>A p.E543K (on ENST00000308378 / NM_001366158.1; = p.E884K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs867011458, COSV57706145; called by muse, mutect2, varscan2
- ZC3H18 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 247/679 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.553); catalogued as rs746618509; called by muse, mutect2, varscan2
- ZC3H4 | c.3826C>T p.P1276S | Missense Mutation (SNP) | VAF 229/647 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53415250; called by muse, mutect2, varscan2
- ZNF208 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 103/360 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV68109545; called by muse, mutect2, varscan2
- AC098582.1 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACCSL | c.1537T>G p.L513V | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ACTRT1 | c.5T>A p.F2Y | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ADAMTS14 | c.3367G>A p.G1123R | Missense Mutation (SNP) | VAF 216/418 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ADH1C | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 154/459 reads (34%) | called by muse, mutect2, varscan2
- ALMS1 | c.9916G>A p.D3306N | Missense Mutation (SNP) | VAF 101/384 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD18A | c.1340G>A p.W447* | Nonsense Mutation (SNP) | VAF 142/313 reads (45%) | called by muse, mutect2, varscan2
- ANKRD9 | c.759_763del p.D254Afs*9 | Frame Shift Del (DEL) | VAF 248/480 reads (52%) | called by mutect2, pindel, varscan2
- APC2 | c.3898G>A p.A1300T | Missense Mutation (SNP) | VAF 216/635 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AREG | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 90/331 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- ARID1A | c.6292G>T p.E2098* | Nonsense Mutation (SNP) | VAF 217/592 reads (37%) | called by muse, mutect2, varscan2
- C1orf94 | c.645G>T p.E215D (on ENST00000488417 / NM_001134734.2; = p.E25D on NM_032884.5) | Missense Mutation (SNP) | VAF 150/472 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); called by mutect2, varscan2
- C4orf50 | c.614G>A p.G205E (on ENST00000324058; = p.G1437E on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CAMK4 | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 140/343 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASP7 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 158/309 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CBLL2 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 229/438 reads (52%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CBX2 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 260/706 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCDC39 | c.776A>G p.E259G | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- CDC42EP4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 217/656 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- CDH5 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 124/371 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CEACAM20 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 116/374 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- CERS1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 98/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CES4A | c.1126A>G p.I376V | Missense Mutation (SNP) | VAF 158/519 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CFAP65 | c.5372G>A p.G1791D | Missense Mutation (SNP) | VAF 229/702 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD1L | c.1579_1582delinsTTC p.A527Ffs*10 | Frame Shift Del (DEL) | VAF 131/434 reads (30%) | called by pindel, varscan2*
- COLEC12 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 195/627 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPAMD8 | c.3916A>T p.K1306* (on ENST00000651564; = p.K1259* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 140/430 reads (33%) | called by muse, mutect2, varscan2
- CR2 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 129/444 reads (29%) | called by muse, mutect2, varscan2
- CYP2D7 | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 268/658 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF17 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 122/321 reads (38%) | called by muse, mutect2, varscan2
- DCDC2C | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 230/424 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- DCUN1D3 | c.151A>C p.I51L | Missense Mutation (SNP) | VAF 204/562 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHODH | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 112/407 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- DLGAP2 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 162/474 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH17 | c.5903+1G>A p.X1968_splice | Splice Site (SNP) | VAF 104/265 reads (39%) | called by muse, mutect2, varscan2
- DNAH2 | c.10189C>G p.P3397A | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOHH | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 272/856 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DSCAM | c.5747C>T p.P1916L | Missense Mutation (SNP) | VAF 154/445 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EGFLAM | c.1686G>A p.G562= | Splice Region (SNP) | VAF 102/222 reads (46%) | called by muse, mutect2, varscan2
- EPX | c.2123A>G p.N708S | Missense Mutation (SNP) | VAF 131/426 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ERICH6 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 235/768 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.277); called by muse, varscan2
- FAM171A1 | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 134/248 reads (54%) | called by muse, mutect2, varscan2
- FAM83E | c.200T>C p.L67S | Missense Mutation (SNP) | VAF 204/677 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FECH | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 110/424 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FHOD1 | c.475T>G p.S159A | Missense Mutation (SNP) | VAF 132/436 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FLG | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 196/620 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, varscan2
- FREM3 | c.2410T>C p.Y804H | Missense Mutation (SNP) | VAF 213/551 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GABBR2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 320/467 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- GP1BA | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 107/717 reads (15%) | SIFT tolerated (0.34); called by muse, mutect2, varscan2
- GPR50 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 301/893 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GTF2H3 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 122/358 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HAUS3 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- HAVCR1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 86/471 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HMCN2 | c.14119G>A p.D4707N | Missense Mutation (SNP) | VAF 310/447 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IKZF2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IL1RAP | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 171/518 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ILVBL | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 203/586 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- INHBE | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 219/670 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- INSIG1 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 234/685 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRAG2 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 151/422 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IVL | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 179/468 reads (38%) | called by mutect2, varscan2
- JADE2 | c.817dup p.W273Lfs*12 | Frame Shift Ins (INS) | VAF 142/409 reads (35%) | called by mutect2, pindel, varscan2
- JAKMIP2 | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 86/393 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KANK4 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 193/546 reads (35%) | called by muse, mutect2, varscan2
- KCNA5 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 196/586 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNE3 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 205/388 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIF21B | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 141/460 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KLB | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 173/570 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL13 | c.1907T>G p.V636G | Missense Mutation (SNP) | VAF 165/478 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- KRT16 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 111/313 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRT28 | c.115T>A p.S39T | Missense Mutation (SNP) | VAF 212/623 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- L1CAM | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 210/635 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA3 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 204/616 reads (33%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LEMD3 | c.206A>T p.N69I | Missense Mutation (SNP) | VAF 180/545 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- LIFR | c.2783C>A p.P928Q | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- LMTK3 | c.648G>A p.G216= | Splice Region (SNP) | VAF 116/382 reads (30%) | called by muse, varscan2
- LOXHD1 | c.4109G>A p.G1370E | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LOXHD1 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 144/431 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- LPO | c.1765A>T p.K589* | Nonsense Mutation (SNP) | VAF 206/604 reads (34%) | called by muse, mutect2, varscan2
- MAP3K1 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 84/455 reads (18%) | called by muse, mutect2, varscan2
- MAPK10 | c.1454G>A p.R485K | Missense Mutation (SNP) | VAF 150/402 reads (37%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- MDGA2 | c.1012G>A p.G338R (on ENST00000399232 / NM_001113498.2; = p.G40R on NM_182830.4) | Missense Mutation (SNP) | VAF 169/509 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MEIS3 | c.827T>G p.I276S | Missense Mutation (SNP) | VAF 126/434 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- MME | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 130/416 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MRAP2 | c.615T>A p.D205E | Missense Mutation (SNP) | VAF 198/324 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MRPS35 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 111/310 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- MUC16 | c.4951C>T p.P1651S | Missense Mutation (SNP) | VAF 210/674 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2
- MYLK | c.3812G>A p.W1271* | Nonsense Mutation (SNP) | VAF 149/439 reads (34%) | called by muse, mutect2, varscan2
- NACC1 | c.882T>G p.D294E | Missense Mutation (SNP) | VAF 86/560 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NANOGNB | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 166/468 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.187); called by mutect2, varscan2
- NCKAP5 | c.2774A>T p.K925I | Missense Mutation (SNP) | VAF 219/579 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- NCKAP5 | c.549A>T p.K183N | Missense Mutation (SNP) | VAF 162/424 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- NCOA2 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 143/452 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NEGR1 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NLGN4X | c.1373A>T p.D458V | Missense Mutation (SNP) | VAF 274/515 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- OR6J1 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 147/414 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ORC2 | c.1733G>C p.*578Sext*53 | Nonstop Mutation (SNP) | VAF 67/223 reads (30%) | called by muse, mutect2, varscan2
- PACS2 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 128/257 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- PCDHB6 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 273/767 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHLDB3 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 190/632 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.3375G>A p.E1125= | Splice Region (SNP) | VAF 74/184 reads (40%) | called by muse, mutect2, varscan2
- PPARGC1A | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 139/494 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPEF2 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 126/411 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PRKDC | c.11204C>T p.P3735L | Missense Mutation (SNP) | VAF 165/427 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PXDNL | c.2080T>A p.L694M | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- RASSF2 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 99/193 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- RBM17 | c.481T>A p.Y161N | Missense Mutation (SNP) | VAF 267/577 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- REELD1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 128/415 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RERE | c.4090T>C p.F1364L | Missense Mutation (SNP) | VAF 42/826 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2
- RFX7 | c.3336T>A p.N1112K (on ENST00000559447 / NM_001368074.1; = p.N1209K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 183/520 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RGS22 | c.1150A>C p.S384R | Missense Mutation (SNP) | VAF 176/554 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RNF19B | c.1949G>A p.S650N | Missense Mutation (SNP) | VAF 186/557 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNGTT | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 142/265 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ROBO4 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 162/285 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SALL1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 187/562 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- SCN2A | c.2141C>T p.T714I | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- SEC16B | c.1878C>A p.F626L | Missense Mutation (SNP) | VAF 132/425 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SENP6 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 197/317 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEZ6L2 | c.1762C>T p.P588S (on ENST00000308713 / NM_001114099.3; = p.P518S on NM_012410.4) | Missense Mutation (SNP) | VAF 209/606 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SGMS2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 140/417 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC10A4 | c.714_719dup p.T240_L241dup | In Frame Ins (INS) | VAF 136/460 reads (30%) | called by mutect2, varscan2
- SLC22A6 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 156/303 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC25A25 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 246/390 reads (63%) | called by muse, mutect2, varscan2
- SLC35F4 | c.1075T>C p.F359L (on ENST00000339762 / NM_001352015.2; = p.F323L on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/498 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLITRK2 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 229/649 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLTM | c.363T>G p.D121E | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNRNP200 | c.3139C>T p.P1047S | Missense Mutation (SNP) | VAF 176/489 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ST6GALNAC2 | c.995A>T p.K332I | Missense Mutation (SNP) | VAF 122/352 reads (35%) | PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- STIL | c.2515C>T p.P839S | Missense Mutation (SNP) | VAF 170/462 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- SYNE1 | c.2251G>T p.D751Y (on ENST00000367255 / NM_182961.4; = p.D758Y on NM_033071.3) | Missense Mutation (SNP) | VAF 175/306 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SYT17 | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 132/404 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAOK1 | c.858del p.E287Kfs*4 | Frame Shift Del (DEL) | VAF 122/367 reads (33%) | called by mutect2, pindel*, varscan2
- TAS2R39 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 153/508 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TDGF1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TDRD15 | c.5453G>A p.G1818E | Missense Mutation (SNP) | VAF 113/242 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGM6 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 145/273 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TH | c.448C>T p.Q150* (on ENST00000381178 / NM_199292.3; = p.Q119* on NM_000360.4) | Nonsense Mutation (SNP) | VAF 180/365 reads (49%) | called by muse, mutect2, varscan2
- THADA | c.1454T>C p.M485T | Missense Mutation (SNP) | VAF 201/477 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TMUB1 | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 233/716 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOP2A | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 127/351 reads (36%) | called by muse, mutect2, varscan2
- TRAV7 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 129/410 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TRAV8-2 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 132/382 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TRMT13 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TTPA | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 159/472 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TYK2 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 151/436 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.247); called by muse, varscan2
- UBA6 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT1A10 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 190/559 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UNC13A | c.3297G>A p.M1099I | Missense Mutation (SNP) | VAF 129/404 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- URB2 | c.4424A>T p.Y1475F | Missense Mutation (SNP) | VAF 152/455 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- USP8 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 162/443 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- VCAN | c.3533T>C p.I1178T | Missense Mutation (SNP) | VAF 31/462 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- XKR4 | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 170/507 reads (34%) | called by muse, mutect2, varscan2
- ZC3H18 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF44 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 113/371 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF549 | c.338T>G p.M113R (on ENST00000376233 / NM_001199295.2; = p.M100R on NM_153263.2) | Missense Mutation (SNP) | VAF 136/426 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF579 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 97/658 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ZNF680 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 116/363 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF853 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 245/722 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZPLD1 | c.43C>G p.L15V (on ENST00000466937 / NM_001329788.1; = p.L31V on NM_175056.2) | Missense Mutation (SNP) | VAF 129/448 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABAT | c.9C>T p.S3= | Silent (SNP) | VAF 142/431 reads (33%) | catalogued as rs867072039, COSV51624808; called by muse, mutect2, varscan2
- ACAN | c.939G>A p.K313= | Silent (SNP) | VAF 244/751 reads (32%) | called by muse, mutect2, varscan2
- ACER2 | c.462G>A p.L154= | Silent (SNP) | VAF 144/278 reads (52%) | called by muse, mutect2, varscan2
- ACSM2A | c.393C>T p.L131= (on ENST00000219054; = p.L52= on NM_001308169.2) | Silent (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
- ADAMDEC1 | c.1152C>T p.F384= | Silent (SNP) | VAF 74/235 reads (31%) | catalogued as COSV56473968; called by muse, mutect2, varscan2
- ADAMTS2 | c.2949C>A p.P983= | Silent (SNP) | VAF 192/514 reads (37%) | catalogued as COSV99281043; called by mutect2, varscan2
- ADAMTS9 | c.2706T>C p.L902= | Silent (SNP) | VAF 55/169 reads (33%) | called by muse, mutect2, varscan2
- ADH7 | c.1050G>A p.K350= | Silent (SNP) | VAF 109/389 reads (28%) | called by muse, mutect2, varscan2
- ALB | c.1767G>A p.E589= | Silent (SNP) | VAF 97/386 reads (25%) | called by muse, mutect2, varscan2
- ANK1 | c.2247C>T p.I749= | Silent (SNP) | VAF 107/356 reads (30%) | catalogued as rs1315817030, COSV55882507; called by muse, mutect2, varscan2
- AP002495.1 | c.111G>A p.K37= | Silent (SNP) | VAF 123/269 reads (46%) | called by muse, mutect2, varscan2
- APOOL | c.258G>A p.V86= | Silent (SNP) | VAF 111/378 reads (29%) | called by muse, mutect2, varscan2
- ARAP3 | c.3627C>T p.P1209= | Silent (SNP) | VAF 148/428 reads (35%) | called by muse, mutect2
- ASTN2 | c.2280C>A p.P760= (on ENST00000313400 / NM_001365069.1; = p.P709= on NM_014010.5) | Silent (SNP) | VAF 163/471 reads (35%) | called by muse, mutect2, varscan2
- AXIN1 | c.252G>A p.K84= | Silent (SNP) | VAF 227/628 reads (36%) | called by muse, mutect2, varscan2
- C3 | c.4557C>T p.F1519= | Silent (SNP) | VAF 127/383 reads (33%) | called by muse, mutect2, varscan2
- CACNA1G | c.2532G>A p.L844= | Silent (SNP) | VAF 197/618 reads (32%) | catalogued as rs771670941; called by muse, mutect2, varscan2
- CCDC54 | c.96C>T p.Y32= | Silent (SNP) | VAF 180/616 reads (29%) | catalogued as COSV53759502; called by muse, mutect2
- CDC42EP4 | c.129C>T p.A43= | Silent (SNP) | VAF 222/666 reads (33%) | catalogued as rs572079635; called by muse, mutect2, varscan2
- CERS3 | c.786C>T p.T262= | Silent (SNP) | VAF 153/439 reads (35%) | catalogued as rs764401429; called by muse, mutect2, varscan2
- CLEC4M | c.909C>T p.L303= | Silent (SNP) | VAF 188/584 reads (32%) | catalogued as rs756357978; called by muse, mutect2
- CNGB1 | c.822G>A p.G274= | Silent (SNP) | VAF 119/401 reads (30%) | catalogued as rs1379064484, COSV51900612, COSV99212212; called by muse, mutect2, varscan2
- CNR1 | c.687C>T p.T229= | Silent (SNP) | VAF 234/375 reads (62%) | called by muse, mutect2, varscan2
- COL11A1 | c.2830C>T p.L944= | Silent (SNP) | VAF 126/409 reads (31%) | called by muse, mutect2, varscan2
- COL20A1 | c.2109C>T p.V703= | Silent (SNP) | VAF 174/606 reads (29%) | catalogued as rs1313625471; called by muse, varscan2
- COL20A1 | c.2110C>T p.L704= | Silent (SNP) | VAF 203/656 reads (31%) | called by muse, mutect2, varscan2
- CR2 | c.2583C>T p.N861= | Silent (SNP) | VAF 117/374 reads (31%) | catalogued as rs535893935; called by muse, mutect2, varscan2
- CSMD1 | c.1464C>T p.S488= (on ENST00000520002; = p.S487= on NM_033225.6) | Silent (SNP) | VAF 119/381 reads (31%) | catalogued as rs1441727399, COSV68261170; called by muse, mutect2, varscan2
- CYLC2 | c.103C>T p.L35= | Silent (SNP) | VAF 267/394 reads (68%) | called by muse, mutect2, varscan2
- DHODH | c.1125C>T p.A375= | Silent (SNP) | VAF 114/409 reads (28%) | called by muse, mutect2, varscan2
- DNAJC13 | c.2271T>C p.N757= | Silent (SNP) | VAF 57/243 reads (23%) | called by muse, mutect2, varscan2
- DOCK3 | c.4512G>A p.V1504= | Silent (SNP) | VAF 54/176 reads (31%) | catalogued as rs367627913; called by muse, mutect2, varscan2
- DRAM2 | c.450C>T p.I150= | Silent (SNP) | VAF 176/526 reads (33%) | called by muse, mutect2, varscan2
- DSPP | c.981G>A p.E327= | Silent (SNP) | VAF 166/493 reads (34%) | catalogued as COSV56808531; called by muse, mutect2, varscan2
- EPHA6 | c.1290G>A p.R430= | Silent (SNP) | VAF 102/318 reads (32%) | called by muse, mutect2, varscan2
- EPHA6 | c.2379C>T p.V793= (on ENST00000389672 / NM_001080448.3; = p.V185= on NM_173655.4) | Silent (SNP) | VAF 107/293 reads (37%) | called by muse, mutect2, varscan2
- EPHB2 | c.1011G>A p.E337= | Silent (SNP) | VAF 169/484 reads (35%) | called by muse, mutect2, varscan2
- ERICH6 | c.57G>A p.K19= | Silent (SNP) | VAF 238/771 reads (31%) | catalogued as rs1218130941; called by muse, varscan2
- ESRRA | c.567G>A p.K189= | Silent (SNP) | VAF 164/337 reads (49%) | called by muse, mutect2, varscan2
- EYA2 | c.699G>A p.A233= | Silent (SNP) | VAF 204/544 reads (38%) | catalogued as rs746177660, COSV57938778; called by muse, mutect2, varscan2
- F8 | c.4692C>T p.P1564= | Silent (SNP) | VAF 242/670 reads (36%) | called by muse, mutect2, varscan2
- FAM151A | c.1656G>A p.R552= | Silent (SNP) | VAF 193/566 reads (34%) | called by muse, mutect2, varscan2
- FAM83F | c.1005C>T p.H335= | Silent (SNP) | VAF 529/1027 reads (52%) | catalogued as rs763947933; called by muse, mutect2, varscan2
- FBN3 | c.6480C>A p.L2160= | Silent (SNP) | VAF 127/442 reads (29%) | called by muse, mutect2
- FBXO39 | c.921G>A p.P307= | Silent (SNP) | VAF 191/554 reads (34%) | catalogued as rs764013991, COSV58620917; called by muse, mutect2, varscan2
- FER1L5 | c.3888G>A p.G1296= (on ENST00000623019; = p.G1269= on NM_001293083.2) | Silent (SNP) | VAF 182/545 reads (33%) | called by muse, mutect2, varscan2
- FGF12 | c.531C>T p.L177= (on ENST00000454309 / NM_021032.5; = p.L115= on NM_004113.6) | Silent (SNP) | VAF 186/584 reads (32%) | catalogued as rs201262513; called by muse, mutect2, varscan2
- FREM3 | c.2409T>C p.T803= | Silent (SNP) | VAF 213/551 reads (39%) | called by muse, mutect2, varscan2
- GALNT17 | c.783C>T p.S261= | Silent (SNP) | VAF 124/364 reads (34%) | catalogued as rs866747641, COSV100356753, COSV61165144; called by muse, varscan2
- GON4L | c.4380G>A p.E1460= | Silent (SNP) | VAF 174/567 reads (31%) | catalogued as rs759848171; called by mutect2, varscan2
- GPR101 | c.294C>T p.P98= | Silent (SNP) | VAF 246/786 reads (31%) | called by muse, mutect2, varscan2
- GPR39 | c.852C>T p.F284= | Silent (SNP) | VAF 103/315 reads (33%) | catalogued as rs147500982; called by muse, mutect2, varscan2
- GTF2H3 | c.393T>A p.T131= | Silent (SNP) | VAF 123/362 reads (34%) | called by muse, mutect2, varscan2
- IGFL1 | c.57C>T p.L19= | Silent (SNP) | VAF 186/584 reads (32%) | catalogued as rs866967751; called by muse, mutect2, varscan2
- IKBKG | c.510G>A p.L170= | Silent (SNP) | VAF 63/326 reads (19%) | called by muse, mutect2, varscan2
- IKZF2 | c.735G>A p.K245= | Silent (SNP) | VAF 86/294 reads (29%) | catalogued as rs1252484156; called by muse, mutect2, varscan2
- IKZF2 | c.195G>A p.L65= | Silent (SNP) | VAF 151/483 reads (31%) | called by muse, mutect2, varscan2
- IPO13 | c.1260C>T p.F420= | Silent (SNP) | VAF 102/320 reads (32%) | catalogued as rs996734578; called by muse, mutect2, varscan2
- KRT2 | c.1104G>A p.E368= | Silent (SNP) | VAF 117/348 reads (34%) | catalogued as rs759646128; called by muse, mutect2, varscan2
- L1CAM | c.480T>A p.P160= | Silent (SNP) | VAF 214/643 reads (33%) | called by muse, mutect2
- LAMA3 | c.72G>A p.L24= | Silent (SNP) | VAF 188/584 reads (32%) | catalogued as rs761264080; called by muse, varscan2
- LLGL2 | c.2676G>A p.R892= | Silent (SNP) | VAF 181/555 reads (33%) | called by muse, mutect2, varscan2
- LRATD1 | c.291C>T p.S97= | Silent (SNP) | VAF 108/513 reads (21%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.3057C>T p.I1019= | Silent (SNP) | VAF 148/394 reads (38%) | catalogued as rs368707228; called by muse, mutect2, varscan2
- MAGEC1 | c.1791G>A p.Q597= | Silent (SNP) | VAF 233/819 reads (28%) | catalogued as COSV53573651; called by muse, mutect2, varscan2
- MAGEL2 | c.54G>A p.P18= | Silent (SNP) | VAF 200/592 reads (34%) | called by muse, mutect2, varscan2
- MEIS3 | c.828C>A p.I276= | Silent (SNP) | VAF 125/429 reads (29%) | called by muse, mutect2, varscan2
- MGAM2 | c.1638C>A p.A546= | Silent (SNP) | VAF 43/319 reads (13%) | called by muse, mutect2, varscan2
- MID2 | c.264G>A p.R88= | Silent (SNP) | VAF 217/660 reads (33%) | called by muse, mutect2, varscan2
- MPRIP | c.2379C>A p.S793= | Silent (SNP) | VAF 181/315 reads (57%) | called by mutect2, varscan2
- MRO | c.363C>T p.I121= | Silent (SNP) | VAF 198/580 reads (34%) | called by muse, mutect2, varscan2
- MUC16 | c.39822G>T p.L13274= | Silent (SNP) | VAF 95/338 reads (28%) | catalogued as COSV66691917; called by muse, mutect2, varscan2
- MYO16 | c.483C>T p.I161= | Silent (SNP) | VAF 131/257 reads (51%) | called by muse, mutect2, varscan2
- MYO1A | c.1845G>A p.L615= | Silent (SNP) | VAF 201/608 reads (33%) | called by muse, mutect2, varscan2
- NDST3 | c.2175C>T p.I725= | Silent (SNP) | VAF 160/527 reads (30%) | called by muse, mutect2, varscan2
- OR10G3 | c.849C>T p.F283= | Silent (SNP) | VAF 184/514 reads (36%) | called by muse, mutect2, varscan2
- OR2G2 | c.423C>T p.I141= | Silent (SNP) | VAF 184/535 reads (34%) | catalogued as COSV100189962, COSV60739978; called by muse, mutect2, varscan2
- OR4K15 | c.840C>T p.F280= (on ENST00000305051; = p.F256= on NM_001005486.1) | Silent (SNP) | VAF 161/496 reads (32%) | catalogued as rs776523087, COSV100521112, COSV100521168; called by muse, mutect2, varscan2
- OR56A4 | c.537G>A p.V179= | Silent (SNP) | VAF 171/325 reads (53%) | called by muse, mutect2, varscan2
- OR7G2 | c.87T>G p.A29= | Silent (SNP) | VAF 38/712 reads (5%) | catalogued as rs1308680811; called by muse, mutect2
- OR8G1 | c.315C>T p.L105= | Silent (SNP) | VAF 167/351 reads (48%) | catalogued as rs764095532, COSV58379860; called by muse, mutect2, varscan2
- P4HTM | c.426G>A p.P142= | Silent (SNP) | VAF 84/228 reads (37%) | catalogued as rs755636277; called by muse, mutect2, varscan2
- PACS1 | c.1584T>C p.S528= | Silent (SNP) | VAF 211/383 reads (55%) | called by muse, mutect2, varscan2
- PATZ1 | c.1369C>T p.L457= | Silent (SNP) | VAF 289/446 reads (65%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1725C>T p.P575= | Silent (SNP) | VAF 271/763 reads (36%) | called by muse, mutect2, varscan2
- PDE6A | c.45G>A p.S15= | Silent (SNP) | VAF 133/354 reads (38%) | catalogued as rs146811139; called by muse, mutect2, varscan2
- PLSCR3 | c.477C>T p.G159= | Silent (SNP) | VAF 161/307 reads (52%) | called by muse, mutect2, varscan2
- PM20D2 | c.792C>T p.I264= | Silent (SNP) | VAF 145/244 reads (59%) | catalogued as rs140686408; called by muse, mutect2, varscan2
- PNOC | c.315C>T p.F105= | Silent (SNP) | VAF 254/702 reads (36%) | catalogued as COSV57284151; called by muse, mutect2, varscan2
- POLQ | c.4539T>A p.L1513= | Silent (SNP) | VAF 98/304 reads (32%) | called by muse, mutect2, varscan2
- PRAM1 | c.1317C>T p.P439= | Silent (SNP) | VAF 279/869 reads (32%) | catalogued as rs1276147418; called by muse, mutect2, varscan2
- PTPRT | c.1185C>T p.I395= | Silent (SNP) | VAF 179/537 reads (33%) | catalogued as rs748326349, COSV61969563; called by muse, mutect2, varscan2
- RAPGEF4 | c.192G>A p.L64= | Silent (SNP) | VAF 105/284 reads (37%) | catalogued as COSV99909513; called by muse, mutect2, varscan2
- RBFOX3 | c.492G>A p.E164= | Silent (SNP) | VAF 111/362 reads (31%) | called by muse, mutect2, varscan2
- RHBDL1 | c.60C>T p.T20= | Silent (SNP) | VAF 189/546 reads (35%) | called by muse, mutect2, varscan2
- RIMBP2 | c.564C>A p.P188= | Silent (SNP) | VAF 158/506 reads (31%) | called by muse, mutect2, varscan2
- RNF207 | c.429G>A p.V143= | Silent (SNP) | VAF 184/565 reads (33%) | catalogued as COSV65008463; called by muse, mutect2, varscan2
- RNGTT | c.1155A>G p.E385= | Silent (SNP) | VAF 234/415 reads (56%) | called by muse, mutect2, varscan2
- ROS1 | c.2193G>A p.L731= | Silent (SNP) | VAF 235/373 reads (63%) | called by muse, mutect2, varscan2
- SALL1 | c.3324C>T p.V1108= | Silent (SNP) | VAF 211/621 reads (34%) | called by muse, mutect2, varscan2
- SALL1 | c.2235G>A p.T745= | Silent (SNP) | VAF 168/518 reads (32%) | catalogued as rs778105407, COSV51752928; called by muse, mutect2, varscan2
- SAP30L | c.384G>A p.L128= | Silent (SNP) | VAF 69/392 reads (18%) | catalogued as rs1001303619; called by muse, mutect2, varscan2
- SEZ6L2 | c.183G>A p.R61= | Silent (SNP) | VAF 138/425 reads (32%) | called by muse, mutect2, varscan2
- SLC10A3 | c.1155C>T p.I385= | Silent (SNP) | VAF 236/776 reads (30%) | catalogued as rs1462399845; called by muse, varscan2
- SLC22A10 | c.282C>T p.P94= | Silent (SNP) | VAF 159/298 reads (53%) | called by muse, mutect2, varscan2
- SLC26A7 | c.1074C>T p.F358= | Silent (SNP) | VAF 134/381 reads (35%) | called by muse, mutect2, varscan2
- SLC2A4RG | c.1158G>A p.L386= | Silent (SNP) | VAF 113/373 reads (30%) | catalogued as rs372035850; called by muse, mutect2, varscan2
- SLC35G3 | c.930C>T p.I310= | Silent (SNP) | VAF 261/730 reads (36%) | catalogued as rs866561974; called by muse, mutect2, varscan2
- SLC4A10 | c.2176C>T p.L726= (on ENST00000446997 / NM_001354461.2; = p.L696= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 153/530 reads (29%) | catalogued as COSV99765598; called by muse, mutect2, varscan2
- SLC6A2 | c.732C>T p.V244= | Silent (SNP) | VAF 166/559 reads (30%) | catalogued as rs1210824562; called by muse, mutect2, varscan2
- SLC9A2 | c.447C>T p.I149= | Silent (SNP) | VAF 160/534 reads (30%) | catalogued as rs143241362, COSV99296958; called by muse, mutect2, varscan2
- SLC9A7 | c.600G>A p.K200= | Silent (SNP) | VAF 112/213 reads (53%) | called by muse, mutect2, varscan2
- SLITRK5 | c.2415A>G p.P805= | Silent (SNP) | VAF 295/543 reads (54%) | catalogued as rs985109359; called by muse, mutect2, varscan2
- SORBS1 | c.123C>T p.I41= | Silent (SNP) | VAF 145/276 reads (53%) | catalogued as rs1388317015, COSV53360585; called by muse, mutect2, varscan2
- SORCS2 | c.1755C>T p.I585= | Silent (SNP) | VAF 148/417 reads (35%) | called by muse, mutect2, varscan2
- SPHKAP | c.4059G>A p.A1353= | Silent (SNP) | VAF 161/477 reads (34%) | catalogued as rs142178318, COSV60874106; called by muse, mutect2, varscan2
- SPTBN5 | c.4554C>T p.A1518= | Silent (SNP) | VAF 165/481 reads (34%) | catalogued as rs1298518570; called by muse, mutect2, varscan2
- SREBF2 | c.3253C>T p.L1085= | Silent (SNP) | VAF 381/780 reads (49%) | called by muse, mutect2, varscan2
- SRRM2 | c.2355C>T p.C785= | Silent (SNP) | VAF 191/584 reads (33%) | called by muse, mutect2, varscan2
- STYXL2 | c.2157C>T p.S719= | Silent (SNP) | VAF 192/609 reads (32%) | catalogued as COSV54809638; called by muse, mutect2, varscan2
- SUGT1 | c.907T>C p.L303= (on ENST00000343788 / NM_001130912.3; = p.L271= on NM_006704.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 149/282 reads (53%) | called by muse, mutect2, varscan2
- TBC1D2 | c.1341C>T p.F447= | Silent (SNP) | VAF 291/425 reads (68%) | catalogued as rs766557404, COSV59788737; called by muse, mutect2, varscan2
- THOC6 | c.492C>T p.L164= | Silent (SNP) | VAF 143/460 reads (31%) | called by muse, mutect2, varscan2
- TIMP4 | c.444G>A p.L148= | Silent (SNP) | VAF 163/296 reads (55%) | called by muse, mutect2, varscan2
- TMC3 | c.3024C>T p.A1008= | Silent (SNP) | VAF 180/556 reads (32%) | catalogued as rs1456390557; called by muse, mutect2, varscan2
- TMEM120B | c.930C>T p.F310= | Silent (SNP) | VAF 138/393 reads (35%) | called by muse, mutect2, varscan2
- TMEM132B | c.2685G>A p.T895= | Silent (SNP) | VAF 181/558 reads (32%) | catalogued as rs201343262; called by muse, mutect2, varscan2
- TMEM132C | c.240G>A p.R80= | Silent (SNP) | VAF 202/598 reads (34%) | called by muse, mutect2, varscan2
- TMPO | c.1267C>T p.L423= | Silent (SNP) | VAF 120/324 reads (37%) | catalogued as rs1465207471; called by muse, mutect2, varscan2
- TNRC18 | c.6244C>T p.L2082= | Silent (SNP) | VAF 205/629 reads (33%) | catalogued as COSV60308964; called by muse, mutect2, varscan2
- TRAV26-1 | c.258G>A p.K86= | Silent (SNP) | VAF 119/345 reads (34%) | catalogued as rs369822978; called by muse, mutect2, varscan2
- TRAV8-4 | c.33G>A p.V11= | Silent (SNP) | VAF 107/402 reads (27%) | called by muse, mutect2, varscan2
- TRIM65 | c.501C>T p.S167= | Silent (SNP) | VAF 148/439 reads (34%) | catalogued as rs1459627146; called by muse, mutect2, varscan2
- TRPC5 | c.309C>T p.A103= | Silent (SNP) | VAF 234/745 reads (31%) | called by muse, mutect2, varscan2
- TTI1 | c.372C>T p.I124= | Silent (SNP) | VAF 116/378 reads (31%) | catalogued as COSV65063058; called by muse, mutect2, varscan2
- TTLL6 | c.1890C>T p.F630= (on ENST00000393382 / NM_001130918.3; = p.F323= on NM_173623.3) | Silent (SNP) | VAF 193/601 reads (32%) | catalogued as rs762905437; called by muse, mutect2, varscan2
- TTN | c.26385C>T p.A8795= (on ENST00000591111; = p.A7868= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/308 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.19917G>A p.P6639= (on ENST00000591111; = p.P5712= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 277/405 reads (68%) | catalogued as rs367929968; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.1785C>T p.H595= | Silent (SNP) | VAF 117/374 reads (31%) | catalogued as rs1561432115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- URB2 | c.4425C>T p.Y1475= | Silent (SNP) | VAF 153/459 reads (33%) | called by muse, mutect2, varscan2
- WDR33 | c.279C>T p.V93= | Silent (SNP) | VAF 90/291 reads (31%) | catalogued as COSV59254150; called by muse, mutect2, varscan2
- WDR90 | c.3831C>T p.L1277= | Silent (SNP) | VAF 197/600 reads (33%) | catalogued as rs200439148; called by muse, mutect2, varscan2
- YLPM1 | c.3516A>G p.E1172= | Silent (SNP) | VAF 149/306 reads (49%) | catalogued as rs778327295; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1497C>A | Intron (SNP) | VAF 181/551 reads (33%) | catalogued as COSV63751907; called by muse, mutect2, varscan2
- C15orf65 | c.19-105C>T | Intron (SNP) | VAF 106/346 reads (31%) | called by muse, mutect2, varscan2
- C3orf85 | c.-1C>T | 5'UTR (SNP) | VAF 143/390 reads (37%) | called by muse, mutect2, varscan2
- CDH8 | c.*685C>T | 3'UTR (SNP) | VAF 126/424 reads (30%) | called by muse, mutect2
- CR1 | c.487+12105C>T | Intron (SNP) | VAF 210/731 reads (29%) | called by muse, mutect2, varscan2
- FBLN1 | c.186-2380C>T | Intron (SNP) | VAF 362/718 reads (50%) | called by muse, mutect2, varscan2
- GREB1 | c.901+62G>A | Intron (SNP) | VAF 133/677 reads (20%) | called by muse, mutect2, varscan2
- KCNAB1 | c.*323G>A | 3'UTR (SNP) | VAF 115/411 reads (28%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-16225C>T | Intron (SNP) | VAF 102/225 reads (45%) | called by muse, mutect2, varscan2
- NCF4 | c.758+97C>T | Intron (SNP) | VAF 510/751 reads (68%) | called by muse, mutect2, varscan2
- RIMS2 | c.3821+939G>A | Intron (SNP) | VAF 130/421 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.10360+1211G>A | Intron (SNP) | VAF 113/365 reads (31%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.568+196C>T | Intron (SNP) | VAF 193/304 reads (63%) | called by muse, mutect2, varscan2
